Somatic mutation profile of tumor specimen TCGA-FA-A4BB-01A (aliquot TCGA-FA-A4BB-01A-11D-A31X-10) from TCGA case TCGA-FA-A4BB, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 67.3 years (24,590 days).
Specimen TCGA-FA-A4BB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3eacdd13-dce2-47de-a672-e30b09d0eed9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FA-A4BB-10A (Blood Derived Normal), aliquot TCGA-FA-A4BB-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3caaba86-433d-4bc9-a7cb-e92c165c8fd4

The open-access MAF lists 111 somatic variants for this specimen: 69 protein-altering or splice-affecting, 39 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 39, Nonsense Mutation 6, Splice Site 2, Intron 2, Frame Shift Del 2, In Frame Del 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOTCH2 | c.7198C>T p.R2400* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | hotspot (GDC flag); catalogued as rs1325403451, CM112315, COSV56682519; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.3034C>T p.R1012W | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as rs781006841, COSV99284996; called by muse, varscan2
- AHCYL2 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV100272975; called by muse, mutect2, varscan2
- AHR | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | catalogued as COSV99619361; called by muse, mutect2
- ARAP1 | c.2770G>A p.V924M (on ENST00000393609 / NM_001040118.2; = p.V679M on NM_015242.4) | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV100501617; called by muse, mutect2
- ATRNL1 | c.4035T>A p.S1345R | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100369516; called by muse, mutect2, varscan2
- AURKB | c.1028T>C p.V343A | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100298626; called by muse, mutect2, varscan2
- CBLB | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as rs369966206; called by muse, mutect2, varscan2
- CDK5R1 | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV99912344; called by muse, mutect2
- CLCN3 | c.1005T>G p.F335L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100641603; called by muse, mutect2, varscan2
- COL4A5 | c.3967C>A p.P1323T | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100086723, COSV60362142; called by muse, mutect2, varscan2
- COPRS | c.334T>G p.F112V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.178); catalogued as COSV100188341; called by mutect2, varscan2
- CSPP1 | c.2228A>C p.K743T (on ENST00000676605; = p.K702T on NM_024790.6) | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as COSV99138065; called by mutect2, varscan2
- DEFB114 | c.98A>T p.Y33F | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as COSV100435364; called by muse, mutect2, varscan2
- DIAPH3 | c.1483A>G p.I495V (on ENST00000400324 / NM_001042517.2; = p.I232V on NM_030932.3) | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV99932894; called by muse, mutect2
- DSC1 | c.872C>A p.P291Q | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV99937281; called by muse, mutect2, varscan2
- DUSP2 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1244546242, COSV99997009; called by muse, mutect2, varscan2
- EBF1 | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58166381, COSV58173197; called by muse, mutect2, varscan2
- EXD1 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs769539024, COSV100153508; called by mutect2, varscan2
- GNB1L | c.140G>A p.G47D | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100283963; called by muse, mutect2, varscan2
- GP9 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.04); catalogued as rs759941195, COSV56624498; called by muse, mutect2, varscan2
- H2BC12 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV100804581, COSV100804760; called by muse, mutect2, varscan2
- HERC1 | c.6577G>A p.G2193S | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV101496376; called by muse, mutect2, varscan2
- HYDIN | c.5593G>T p.D1865Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59255060, COSV59273918, COSV99992118; called by muse, mutect2
- IFT80 | c.1643C>T p.T548I | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV100424456; called by muse, mutect2
- IGHG1 | c.797G>A p.S266N | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as rs751791072; called by muse, varscan2
- IGHM | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1555378339; called by mutect2, varscan2
- INTS3 | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV59678840; called by muse, mutect2, varscan2
- KIAA1549 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV99649958; called by muse, mutect2, varscan2
- KIF3B | c.1725G>C p.E575D | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as COSV100996331; called by mutect2, varscan2
- KMT2D | c.11386C>T p.Q3796* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV56483498; called by muse, mutect2, varscan2
- KRT37 | c.29G>T p.C10F | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99845290; called by muse, mutect2
- KRT79 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.896); catalogued as COSV100398308; called by mutect2, varscan2
- LAMA1 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs772486258, COSV67531082, COSV67539498; called by muse, mutect2, varscan2
- MIPEP | c.2120C>G p.T707S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.021); catalogued as COSV101193028; called by muse, mutect2
- MN1 | c.2833C>T p.R945C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs1228656383, COSV100179676; called by muse, mutect2, varscan2
- MPEG1 | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99915075; called by muse, mutect2, varscan2
- MPEG1 | c.747C>G p.N249K | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as rs1382625999, COSV99915077; called by muse, varscan2
- NAPSA | c.246T>G p.I82M | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99515736; called by muse, mutect2, varscan2
- NF1 | c.1203T>A p.N401K | Missense Mutation (SNP) | VAF 29/302 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV100646176; called by muse, mutect2
- PEX2 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV63814228; called by muse, mutect2
- PHKA1 | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs782021325, COSV100262554, COSV59806406; called by muse, mutect2, varscan2
- RBM5 | c.2262G>A p.M754I | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100762172; called by muse, mutect2, varscan2
- RIMS2 | c.4567G>A p.V1523I (on ENST00000666250 / NM_001348490.2; = p.V1094I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs774140573, COSV51731487; called by muse, mutect2, varscan2
- SLC37A3 | c.596C>A p.S199Y | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.026); catalogued as COSV100405317; called by muse, mutect2, varscan2
- SMC2 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as rs199917130, COSV99658509; called by muse, mutect2, varscan2
- SPEN | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 21/91 reads (23%) | catalogued as COSV65357313; called by muse, mutect2, varscan2
- SRSF1 | c.366_367del p.R122Sfs*21 | Frame Shift Del (DEL) | VAF 14/146 reads (10%) | catalogued as rs1189726625; called by pindel, varscan2
- SYNE2 | c.17144T>C p.F5715S | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as COSV100646871; called by muse, varscan2
- TAS2R16 | c.729A>G p.I243M | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV99972189; called by muse, mutect2
- TDRD5 | c.1673T>G p.V558G | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99675620; called by muse, mutect2, varscan2
- THSD7A | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749795557, COSV101448547, COSV101448565; called by muse, mutect2, varscan2
- TNC | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV100405087; called by muse, mutect2, varscan2
- TNFRSF13C | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV99351678; called by muse, mutect2, varscan2
- TNFRSF14 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV100859077; called by muse, mutect2, varscan2
- TNFRSF25 | c.542+1G>A p.X181_splice | Splice Site (SNP) | VAF 18/156 reads (12%) | catalogued as rs368544215; called by muse, mutect2, varscan2
- TRPC1 | c.1298-2A>G p.X433_splice (on ENST00000476941 / NM_001251845.2; = p.X399_splice on NM_003304.4) | Splice Site (SNP) | VAF 7/63 reads (11%) | catalogued as rs995473297, COSV99858307; called by muse, mutect2, varscan2
- UBR4 | c.5990C>T p.A1997V | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100920335; called by muse, mutect2, varscan2
- UBR5 | c.8278C>T p.Q2760* | Nonsense Mutation (SNP) | VAF 16/148 reads (11%) | catalogued as COSV99639630; called by muse, mutect2, varscan2
- UNK | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.445); catalogued as COSV99504563; called by muse, mutect2, varscan2
- ZAN | c.6064C>A p.Q2022K | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV100769274; called by muse, mutect2, varscan2
- BMP4 | c.194T>G p.F65C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CXCR5 | c.1082_1083del p.S361* | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by pindel, varscan2
- HLA-DQB1 | c.140G>T p.C47F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGHG1 | c.225C>G p.S75R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- IGHG3 | c.729G>C p.W243C | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MSL2 | c.193_195del p.Y65del | In Frame Del (DEL) | VAF 13/118 reads (11%) | called by mutect2, varscan2
- PCLO | c.11157dup p.V3720Sfs*2 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by mutect2, pindel
- PRAMEF20 | c.596T>A p.L199Q | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS15 | c.33C>T p.F11= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV54503944; called by muse, mutect2
- ADARB1 | c.318G>A p.A106= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as rs201356458, COSV62347759; called by muse, mutect2, varscan2
- ADGRL1 | c.3198C>T p.F1066= (on ENST00000340736 / NM_001008701.3; = p.F1061= on NM_014921.5) | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as rs749222768, COSV61564813, COSV61564887; called by muse, mutect2, varscan2
- ANGPT4 | c.717C>T p.R239= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV67921717; called by muse, mutect2, varscan2
- ANKRD50 | c.3612G>T p.V1204= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as COSV101538892; called by muse, mutect2, varscan2
- BAZ1A | c.4002T>C p.R1334= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as rs1227796865, COSV100701093; called by muse, mutect2
- BTG2 | c.286C>T p.L96= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs760333089, COSV99305603; called by muse, mutect2, varscan2
- C11orf87 | c.225C>T p.I75= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs1357330662, COSV59356919; called by mutect2, varscan2
- C21orf62 | c.9A>T p.P3= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV101212293; called by muse, mutect2, varscan2
- CCN4 | c.576A>G p.P192= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV99136972; called by muse, mutect2, varscan2
- CCN5 | c.582C>T p.C194= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV99509188; called by muse, mutect2, varscan2
- DDX52 | c.381A>C p.L127= | Silent (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- DSEL | c.1467C>A p.P489= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV100025341; called by muse, mutect2, varscan2
- EFCAB6 | c.3666C>T p.N1222= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs1316330819, COSV99412586; called by muse, mutect2
- ERN1 | c.1185A>C p.S395= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV101458394; called by muse, mutect2, varscan2
- FCRLB | c.315G>A p.L105= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as rs1293012794, COSV100396095; called by muse, mutect2
- FGF22 | c.246C>T p.G82= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs770103821, COSV99293638; called by muse, mutect2, varscan2
- HPS3 | c.990A>G p.G330= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV99937162; called by muse, mutect2, varscan2
- IGHM | c.1000C>T p.L334= | Silent (SNP) | VAF 6/58 reads (10%) | called by muse, varscan2
- KCNJ6 | c.411C>T p.N137= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs779332289, COSV55711611; called by muse, mutect2, varscan2
- KCTD3 | c.654A>G p.Q218= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV99378923; called by muse, mutect2
- MPEG1 | c.1998C>T p.T666= | Silent (SNP) | VAF 11/125 reads (9%) | catalogued as COSV99915073; called by muse, mutect2
- MPEG1 | c.1599C>T p.S533= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as rs1375944071, COSV57091202; called by muse, mutect2
- MUC5B | c.12990C>A p.T4330= | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as COSV101500063; called by mutect2, varscan2
- MYH13 | c.96C>T p.F32= | Silent (SNP) | VAF 17/139 reads (12%) | catalogued as rs189377998, COSV52823274; called by muse, mutect2, varscan2
- NLRP9 | c.639C>T p.I213= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as rs747611549, COSV60460615; called by muse, mutect2, varscan2
- NRXN1 | c.414G>A p.V138= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV101276799; called by muse, mutect2, varscan2
- NTM | c.174T>A p.T58= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV100867601; called by muse, mutect2, varscan2
- NUP210 | c.733C>T p.L245= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV99595656; called by muse, mutect2, varscan2
- PCDHA4 | c.1683C>T p.N561= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs1463277099, COSV63542337; called by muse, mutect2, varscan2
- PCDHGA3 | c.1476C>T p.T492= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs753266989, COSV53989469; called by mutect2, varscan2
- PIM3 | c.939T>C p.P313= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs1286563501, COSV100638386; called by muse, mutect2, varscan2
- PYY | c.111C>T p.R37= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as COSV63972450; called by muse, mutect2
- SERBP1 | c.468G>A p.P156= | Silent (SNP) | VAF 22/198 reads (11%) | catalogued as rs569288083, COSV100769055; called by muse, mutect2, varscan2
- SIGLEC10 | c.1111C>T p.L371= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV100218536, COSV100218674; called by mutect2, varscan2
- SLC44A4 | c.795G>A p.V265= | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- UNK | c.39C>T p.S13= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs1405394784, COSV99504567; called by muse, mutect2, varscan2
- WNT2 | c.303A>G p.L101= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99625769; called by muse, mutect2
- ZNF324 | c.1248G>A p.Q416= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV99543151; called by muse, mutect2, varscan2
- IQCJ | c.291+38C>A | Intron (SNP) | VAF 8/105 reads (8%) | catalogued as COSV101188047; called by muse, mutect2
- SEMA6D | c.1647-21_1647-19del | Intron (DEL) | VAF 10/100 reads (10%) | called by pindel, varscan2
- TSPOAP1 | chr17:58331260 A>G | 5'Flank (SNP) | VAF 4/24 reads (17%) | catalogued as rs756348475; called by muse, mutect2
